Somatic mutation profile of tumor specimen C3L-04359-04 (aliquot CPT0243280006) from CPTAC case C3L-04359, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.6 years (14,830 days).
Specimen C3L-04359-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8fc5cdc-ad43-4c4d-b55d-6dd6f157dff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04359-31 (Blood Derived Normal), aliquot CPT0243350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de8c73ee-ff11-4587-8947-f0fbb698ca06

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Frame Shift Del 7, In Frame Del 4, Nonsense Mutation 4, 3'Flank 1, Nonstop Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.4407_4410del p.S1470Lfs*19 | Frame Shift Del (DEL) | VAF 91/292 reads (31%) | catalogued as rs875989784; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 90/255 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 146/431 reads (34%) | hotspot (GDC flag); called by pindel, varscan2
- AMN1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 193/555 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs889986563, COSV55671992; called by muse, mutect2, varscan2
- AMZ2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 125/348 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs573816812, COSV100703195; called by muse, mutect2, varscan2
- ATP10A | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 241/565 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs746806712; called by muse, mutect2, varscan2
- BPIFB1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.561); catalogued as rs767225361; called by muse, mutect2, varscan2
- CAMTA2 | c.3337C>T p.R1113* | Nonsense Mutation (SNP) | VAF 10/173 reads (6%) | catalogued as rs1259536035, COSV52777255; called by muse, mutect2
- ERN2 | c.567del p.M190Wfs*9 | Frame Shift Del (DEL) | VAF 41/123 reads (33%) | catalogued as rs946363982; called by mutect2, pindel, varscan2
- FAM53A | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs770461172; called by muse, mutect2, varscan2
- IFNL2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 127/185 reads (69%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as rs555975722, COSV100122026; called by muse, mutect2, varscan2
- MX2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 19/315 reads (6%) | catalogued as rs759060131, COSV58096619; called by muse, mutect2
- NFIX | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 297/837 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100666672, COSV62180396; called by muse, mutect2, varscan2
- OR2J1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 148/447 reads (33%) | catalogued as rs768986758, COSV101013689; called by muse, mutect2
- PIGR | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 130/365 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs373783045, COSV62904307; called by muse, mutect2, varscan2
- BOD1L1 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CHD8 | c.1123_1124del p.L375Vfs*45 (on ENST00000646647 / NM_001170629.2; = p.L96Vfs*45 on NM_020920.4) | Frame Shift Del (DEL) | VAF 138/470 reads (29%) | called by pindel, varscan2
- CIC | c.4031_4032del p.S1344Cfs*17 | Frame Shift Del (DEL) | VAF 66/122 reads (54%) | called by pindel, varscan2
- COBL | c.2311T>C p.W771R | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYGB | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 166/368 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUBP1 | c.1028_1029del p.L343Pfs*7 | Frame Shift Del (DEL) | VAF 161/257 reads (63%) | called by mutect2, pindel, varscan2
- GRK5 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 170/430 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HECTD4 | c.7780G>A p.D2594N | Missense Mutation (SNP) | VAF 184/472 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGFALS | c.1816T>C p.*606Rext*55 | Nonstop Mutation (SNP) | VAF 79/202 reads (39%) | called by muse, mutect2, varscan2
- KCNK1 | c.800_802del p.F267del | In Frame Del (DEL) | VAF 93/251 reads (37%) | called by mutect2, pindel, varscan2
- NLRP4 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 142/233 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NOTCH1 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 262/632 reads (41%) | called by muse, varscan2
- PLAT | c.1399_1401del p.H467del | In Frame Del (DEL) | VAF 109/269 reads (41%) | called by mutect2, pindel, varscan2
- POLQ | c.6169_6170del p.M2057Efs*18 | Frame Shift Del (DEL) | VAF 55/197 reads (28%) | called by mutect2, pindel, varscan2
- RHBDF2 | c.1910A>G p.D637G | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SALL2 | c.1140_1143del p.K380Nfs*52 | Frame Shift Del (DEL) | VAF 77/228 reads (34%) | called by mutect2, pindel, varscan2
- SLC50A1 | c.214_216del p.V72del | In Frame Del (DEL) | VAF 87/227 reads (38%) | called by pindel, varscan2
- TEX35 | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCLRE1C | c.651C>A p.T217= (on ENST00000378278 / NM_001350965.2; = p.T102= on NM_022487.4) | Silent (SNP) | VAF 283/763 reads (37%) | called by muse, mutect2, varscan2
- DTX2 | c.795C>T p.N265= | Silent (SNP) | VAF 22/290 reads (8%) | catalogued as rs765845959, COSV56862318; called by muse, mutect2
- HIVEP1 | c.6435G>C p.V2145= | Silent (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- KIAA1549 | c.4515C>T p.A1505= | Silent (SNP) | VAF 112/295 reads (38%) | catalogued as rs376635509; called by muse, mutect2, varscan2
- NPAP1 | c.621T>C p.P207= | Silent (SNP) | VAF 74/158 reads (47%) | catalogued as rs778525815; called by muse, mutect2
- P2RY8 | c.498G>A p.P166= | Silent (SNP) | VAF 129/337 reads (38%) | catalogued as rs370702297, COSV67177127; called by muse, mutect2, varscan2
- SLC30A9 | c.1347C>G p.L449= | Silent (SNP) | VAF 68/211 reads (32%) | called by muse, mutect2, varscan2
- TRGV5 | c.36G>T p.L12= | Silent (SNP) | VAF 82/285 reads (29%) | called by muse, mutect2, varscan2
- AURKB | c.-14dup | 5'UTR (INS) | VAF 90/253 reads (36%) | called by pindel, varscan2
- PPFIBP2 | chr11:7655491 G>A | 3'Flank (SNP) | VAF 104/256 reads (41%) | catalogued as rs751652825; called by muse, mutect2, varscan2
- RARA | c.*284C>T | 3'UTR (SNP) | VAF 82/202 reads (41%) | catalogued as rs149687193, COSV99565579; called by muse, mutect2, varscan2
